Gene-level copy-number profile of tumor specimen TCGA-A2-A0CK-01A from TCGA case TCGA-A2-A0CK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.5 years (22,094 days).
Specimen TCGA-A2-A0CK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.da561a17-8bdc-4bbb-b6be-c4fe38e5b1b9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0CK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ae91a8ef-9d9f-4345-8126-1f872c61bf34

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,808; copy number 3: 925; copy number 4: 52,203; copy number 5: 97; copy number 6: 2,604; copy number 8: 113; copy number 24: 17; copy number 26: 9; copy number 29: 11; copy number 37: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0CK-01A-11D-A227-01): tumor purity 0.69, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 70 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,294,151–71,568,934, 58 genes, copy number 24–37: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1.
- chr11:71,579,728–71,579,848, 1 gene, copy number 24: KRTAP5-14P.
- chr11:72,685,069–72,843,674, 10 genes, copy number 29: ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2.
- chr11:72,869,544–72,869,650, 1 gene, copy number 29: RNU6-672P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
